FM case AD1940 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Vagina.
https://portal.gdc.cancer.gov/cases/b1b3f08a-5317-42be-8fd0-4558a5c554f9

Female, 57.1 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the vagina. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
